Somatic mutation profile of tumor specimen TCGA-L5-A4OS-01A (aliquot TCGA-L5-A4OS-01A-11D-A28B-09) from TCGA case TCGA-L5-A4OS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A4OS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b957e366-5899-4c46-9628-1e6e89854345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OS-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OS-11A-11D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc57174-7e8f-448d-87ae-994718e7bab1

The open-access MAF lists 89 somatic variants for this specimen: 62 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 26, Nonsense Mutation 4, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.405_406del p.C135* | Nonsense Mutation (DEL) | VAF 16/44 reads (36%) | hotspot (GDC flag); catalogued as COSV53087240; called by mutect2, varscan2
- ABRA | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs148548347, COSV61733597; called by muse, mutect2, varscan2
- ACOT12 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100297115; called by muse, mutect2, varscan2
- ALDH3B1 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV50288337, COSV50290850; called by muse, mutect2, varscan2
- ARHGAP31 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV51796095; called by muse, mutect2
- ASNS | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV99446899; called by muse, mutect2
- B4GALNT1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs200510000; called by muse, mutect2, varscan2
- CDC42BPB | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1292947808; called by muse, mutect2, varscan2
- CFAP44 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as rs1300323050, COSV55611785; called by muse, mutect2
- CHRM4 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as rs1187890206; called by muse, mutect2, varscan2
- COL16A1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs573984488, COSV104375215; called by muse, mutect2, varscan2
- CTNNAL1 | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1340694603, COSV57701782; called by muse, mutect2, varscan2
- DUOX2 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs144759209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELL2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1332853499, COSV99428000; called by muse, mutect2, varscan2
- EPHB1 | c.1584C>T p.D528= | Splice Region (SNP) | VAF 7/41 reads (17%) | catalogued as rs1014932094, COSV104432556; called by muse, mutect2, varscan2
- OR2A4 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1227665821; called by muse, mutect2, varscan2
- OR8K1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV54401231, COSV54401510; called by muse, mutect2, varscan2
- PTPRT | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as COSV62012765; called by muse, mutect2
- RPL26L1 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs371090798, COSV54200333; called by muse, mutect2, varscan2
- SLC4A11 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66263057; called by muse, mutect2, varscan2
- SNTA1 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs775740746; called by muse, mutect2, varscan2
- SPDYE3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.159); catalogued as rs577036288, COSV60106717; called by muse, mutect2, varscan2
- TRAF1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs766666979, COSV100875098; called by muse, mutect2, varscan2
- TRIM4 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1036689187, COSV100584252; called by muse, mutect2
- ZNF207 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as rs1275835630; called by muse, mutect2, varscan2
- ZNF485 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as rs752003650, COSV62423968, COSV62424381; called by muse, mutect2, varscan2
- ADAM32 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADGRL4 | c.324A>C p.I108= | Splice Region (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- AL645922.1 | c.1562C>A p.P521H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ANTXR1 | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AOC1 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARIH2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ATP8A2 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBS4 | c.1396C>G p.Q466E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2
- CDH7 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.155); called by muse, varscan2
- COL15A1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DNAJC7 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHX2 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2
- FBN1 | c.3427G>T p.G1143C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMA1 | c.2789A>C p.Q930P (on ENST00000286628 / NM_001161352.2; = p.Q872P on NM_002247.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIMA1 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRFN2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MCC | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MUC15 | c.611A>T p.Y204F | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MUC20 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- NINL | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OCLN | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- OR2AG2 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR5AN1 | c.219C>A p.C73* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- POLR2A | c.4246C>T p.R1416* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- PPIL4 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- R3HDM1 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF17 | c.4167G>C p.L1389F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- RUNX2 | c.483T>A p.D161E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by mutect2, varscan2
- SCN2A | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- SCN5A | c.3900G>C p.K1300N (on ENST00000333535 / NM_198056.3; = p.K1299N on NM_000335.5) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTAN1 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SYT17 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TMPRSS4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPM5 | c.3395C>G p.S1132C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ZNF808 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CHRNB1 | c.1065G>A p.P355= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- COL7A1 | c.7713G>A p.K2571= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs1185510071, COSV60403017; called by muse, mutect2, varscan2
- DOCK4 | c.825C>T p.T275= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs779442359; called by muse, mutect2, varscan2
- DRD5 | c.1293G>A p.E431= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ELFN2 | c.2143C>T p.L715= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- FIGLA | c.330G>A p.A110= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs779683613, COSV60088601; called by muse, mutect2, varscan2
- FZD4 | c.1182C>T p.P394= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs766436611; called by muse, mutect2, varscan2
- GNRH1 | c.195G>A p.T65= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs577363506, COSV52382614; called by muse, mutect2, varscan2
- IGSF3 | c.2631C>T p.H877= (on ENST00000369486 / NM_001007237.3; = p.H897= on NM_001542.4) | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV59588143; called by muse, mutect2, varscan2
- ITPRIP | c.1269C>T p.T423= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs528588716, COSV99532622; called by mutect2, varscan2
- KRT86 | c.93C>G p.P31= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs768727542, COSV99525119; called by muse, varscan2
- MFN1 | c.2040G>T p.L680= | Silent (SNP) | VAF 9/55 reads (16%) | called by mutect2, varscan2
- MUC5AC | c.15411G>A p.P5137= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs543190470, COSV64371223; called by muse, mutect2, varscan2
- NUP93 | c.2364A>G p.Q788= | Silent (SNP) | VAF 32/142 reads (23%) | called by muse, mutect2, varscan2
- OR6K3 | c.823T>C p.L275= (on ENST00000368146; = p.L259= on NM_001005327.2) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs371617141, COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- PAX1 | c.591C>T p.R197= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV68271919; called by muse, mutect2, varscan2
- PLCB4 | c.1794A>T p.S598= | Silent (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- PTPRF | c.2082C>T p.P694= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs750276955; called by muse, mutect2, varscan2
- SCG2 | c.141C>G p.V47= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- SLC6A4 | c.225T>C p.H75= | Silent (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- TCF7 | c.465C>T p.H155= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs561867522; called by mutect2, varscan2
- TMC6 | c.738C>G p.L246= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- TRPS1 | c.696C>T p.Y232= (on ENST00000220888 / NM_001330599.2; = p.Y245= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs199888153; called by muse, mutect2, varscan2
- ZAP70 | c.654G>A p.A218= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs202191985; called by muse, mutect2, varscan2
- ZHX1 | c.1335A>T p.A445= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- ZNF20 | c.1461C>T p.A487= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- SPTB | c.6345+2900C>A | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as COSV61552176; called by muse, mutect2
